Surgical pathology report (de-identified scan), TCGA case TCGA-NC-A5HJ, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CHUV, specimen TCGA-NC-A5HJ-01A (Primary Tumor).

Synoptic translated report

ICD-6-3
Carcinoma, Squamous cell, NO.
8076/3
Site (R) Lung, middle lobe
C34.2
JW 2/1/13

Site : Right lung middle lobe

☐ Central ☒ Peripheral ☐ NA

Number of lesion :

1. Lung squamous cell carcinoma

Tumor size:

1. 7.0 cm (largest diameter)

Visceral pleural invasion: ☒ Yes ☐ No ☐ NA

Chest wall invasion : ☒ Yes ☐ No ☐ NA

Histological diagnosis : Poorly differentiated squamous cell carcinoma

Node status : N0 (0/30)

TNM : pT3 pN0 (0/30) G3 R0

Pathologist signature:

Date:

Diagnostic Discrepancy		✓

Source: NCI Genomic Data Commons file 3f46cb79-d978-422f-8c9a-0b6d4f485d2c (TCGA-NC-A5HJ.2CE6178F-3CFF-4E17-B5AE-1723C6AA6CF9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).